Gene-level copy-number profile of tumor specimen TCGA-CG-4437-01A from TCGA case TCGA-CG-4437, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 83.4 years (30,467 days).
Specimen TCGA-CG-4437-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.a1fa4bad-c3fa-432d-82f0-fc342f3af445.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4437-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/14f514ef-8d2d-48c1-b473-1a02f9a8e5db

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,040; copy number 2: 5,349; copy number 3: 11,949; copy number 4: 28,749; copy number 5: 8,477; copy number 6: 1,975; copy number 7: 1,098; copy number 8: 301; copy number 9: 662; copy number 10: 185; copy number 11: 1; copy number 14: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4437-01A-01D-1799-01): tumor purity 0.37, ploidy 3.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:59,809,269–59,811,310, 1 gene: AC093418.1.
- chr6:162,568,379–162,569,728, 1 gene: KRT8P44.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 875 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:163,455,568–174,378,005, 141 genes, copy number 10–14 (broad region; genes not listed).
- chr3:174,631,823–174,632,064, 1 gene, copy number 10: RN7SKP40.
- chr3:175,473,919–198,222,513, 492 genes, copy number 9–11 (broad region; genes not listed).
- chr8:120,380,761–138,497,261, 241 genes, copy number 9–10 (within-gene range 7–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 601. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
